Gene-level copy-number profile of tumor specimen HTMCP-01-06-00307-01A from CGCI case HTMCP-01-06-00307, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS.
Specimen HTMCP-01-06-00307-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 284096bf-cd3a-44b9-a2a2-38f84cbe774d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00307-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,873 have no estimate.
https://portal.gdc.cancer.gov/files/d3d44e13-4673-4027-af42-cdb17bf2307b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 353; copy number 2: 1,314; copy number 3: 9,673; copy number 4: 25,442; copy number 5: 11,952; copy number 6: 4,562; copy number 7: 41; copy number 8: 3,093; copy number 9: 2,252; copy number 10: 32; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 34 genes (within-gene range 0–3): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,286 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,928,651–160,523,262, 525 genes, copy number 9 (broad region; genes not listed).
- chr1:160,876,540–192,185,815, 586 genes, copy number 9–10 (broad region; genes not listed).
- chr1:192,246,708–192,367,285, 3 genes, copy number 10: AL513175.1, AL513175.2, RGS21.
- chr1:192,716,132–198,540,945, 54 genes, copy number 9: RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031, AL136456.1, AL357793.1, AL357793.2, RPL23AP22, EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1, LINC01724, KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9, NEK7, PRR13P1, ATP6V1G3.
- chr1:199,148,598–248,937,043, 1,097 genes, copy number 9–11 (broad region; genes not listed).
- chr12:100,143,058–101,128,641, 16 genes, copy number 10 (within-gene range 8–10): AC010203.2, GOLGA2P5, RN7SL176P, AC010203.1, MIR1827, ACTR6, DEPDC4, Y_RNA, SCYL2, SLC17A8, NR1H4, AC010200.1, GAS2L3, PIGAP1, ANO4, AC138360.1.
- chr21:10,640,028–13,067,033, 5 genes, copy number 9: AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
